Somatic mutation profile of tumor specimen TCGA-QH-A6CZ-01A (aliquot TCGA-QH-A6CZ-01A-11D-A32B-08) from TCGA case TCGA-QH-A6CZ, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 38.3 years (14,007 days).
Specimen TCGA-QH-A6CZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3831e9d-989a-472f-9afd-e38e8986c052.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QH-A6CZ-10B (Blood Derived Normal), aliquot TCGA-QH-A6CZ-10B-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8a15c89-e11c-4dd0-9556-2ddd38cb0fab

The open-access MAF lists 30 somatic variants for this specimen: 23 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 17, Silent 7, Nonsense Mutation 2, Frame Shift Del 2, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 28/55 reads (51%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACVR1B | c.1141A>G p.M381V | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV99231454; called by muse, mutect2, varscan2
- ASXL3 | c.5020G>A p.E1674K | Missense Mutation (SNP) | VAF 51/95 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.148); catalogued as rs770577167, COSV52461969, COSV99327010; called by muse, mutect2, varscan2
- BRWD1 | c.2776A>G p.R926G | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV100313331; called by muse, mutect2
- CDKN2C | c.100C>T p.Q34* | Nonsense Mutation (SNP) | VAF 6/67 reads (9%) | catalogued as COSV99395843; called by muse, mutect2
- CIC | c.680A>T p.N227I | Missense Mutation (SNP) | VAF 23/29 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM140387, COSV50601715; called by muse, mutect2, varscan2
- COL6A1 | c.1271G>A p.R424Q | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as rs761729281, COSV62615087; ClinVar: uncertain significance; called by muse, varscan2
- CSF2RA | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 64/166 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs200071635, COSV100817689; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EVI2B | c.802T>C p.S268P | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV58365263; called by muse, mutect2
- FUBP1 | c.1300C>T p.Q434* | Nonsense Mutation (SNP) | VAF 5/47 reads (11%) | catalogued as COSV99628524; called by muse, mutect2, varscan2
- IRF3 | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99881057; called by muse, mutect2
- KIAA0895L | c.40C>A p.P14T | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.154); catalogued as COSV51782800, COSV99220489; called by muse, mutect2, varscan2
- MYO5B | c.1249G>T p.V417L | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV99544600; called by muse, mutect2
- PCDHA2 | c.2198C>T p.A733V | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV65364430; called by muse, mutect2
- PRKACG | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.119); catalogued as rs1377610488, COSV99598653; called by muse, mutect2, varscan2
- SLC28A1 | c.810T>G p.I270M | Missense Mutation (SNP) | VAF 75/160 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV99722928; called by muse, mutect2, varscan2
- SRRT | c.1991A>C p.K664T | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.946); catalogued as COSV99574029; called by muse, mutect2, varscan2
- TMEM217 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.01); catalogued as COSV100362495; called by muse, mutect2
- TRPV6 | c.1211A>G p.D404G | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377233085; called by muse, mutect2, varscan2
- WDR81 | c.5795_5796insG p.D1933Rfs*12 (on ENST00000409644 / NM_001163809.2; = p.D882Rfs*12 on NM_152348.4) | Frame Shift Ins (INS) | VAF 16/42 reads (38%) | catalogued as COSV100488819; called by mutect2, varscan2
- CAPN12 | c.1859del p.G620Afs*21 | Frame Shift Del (DEL) | VAF 19/33 reads (58%) | called by mutect2, pindel, varscan2
- CIC | c.2694del p.A900Pfs*24 | Frame Shift Del (DEL) | VAF 8/75 reads (11%) | called by mutect2, pindel, varscan2
- KCNMA1 | c.3205_3243del p.T1069_A1081del (on ENST00000286628 / NM_001161352.2; = p.T1011_A1023del on NM_002247.4) | In Frame Del (DEL) | VAF 16/70 reads (23%) | called by mutect2, pindel
- ABCA13 | c.14874T>C p.C4958= | Silent (SNP) | VAF 21/198 reads (11%) | catalogued as COSV68944194; called by muse, mutect2, varscan2
- ARRDC5 | c.513C>T p.F171= (on ENST00000381781; = p.F157= on NM_001080523.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as rs1451472703, COSV101108100; called by muse, mutect2, varscan2
- DNAH1 | c.5157C>G p.L1719= | Silent (SNP) | VAF 64/168 reads (38%) | catalogued as COSV101325604; called by muse, mutect2, varscan2
- DSP | c.2046C>T p.C682= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as rs771674559, COSV101131258; called by muse, mutect2, varscan2
- NEK10 | c.2112G>A p.E704= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV99835121; called by muse, mutect2, varscan2
- PCDHGC5 | c.876C>T p.L292= | Silent (SNP) | VAF 56/164 reads (34%) | catalogued as COSV99339747; called by muse, mutect2, varscan2
- STAB2 | c.6228C>T p.D2076= | Silent (SNP) | VAF 16/219 reads (7%) | catalogued as rs767352468, COSV66335952; called by muse, mutect2
